TCGA case TCGA-DU-6392 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fcd9e1c4-bddb-4856-844c-03df48fba499

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 35.1 years (12,836 days); Year of diagnosis: 1993; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6,423 days (17.6 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Parietal; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 78 days; Number of cycles: 1; Treatment dose: 300 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 78 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 17 days; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Treatment intent type: Adjuvant; Regimen or line of therapy: PCV; Days to treatment start: 109 days; Days to treatment end: 443 days (1.2 years); Number of cycles: 6; Route of administration: Oral.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Metastasis of diagnosis 1 (Astrocytoma, anaplastic). Age at diagnosis: 37.7 years (13,786 days); Days to diagnosis: 950 days (2.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 950 days (2.6 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,055 days (2.9 years); Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 950 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 950 days (2.6 years).
- Day 950 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 950 days (2.6 years).
- Days to follow up: 6,423 days (17.6 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-6392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-DU-6392-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DU-6392-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DU-6392-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-6392-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Parietal Lobe; History seizures: Yes; First symptom longest duration: 0 - 30 Days; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Radiation treatment 1: Radiation type other: Stereotactic Radiosurgery.
- Follow-up form: Treatment outcome first course: Progressive Disease; New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No; Treatment outcome at TCGA followup: Stable Disease; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 6,423 days; disease-specific survival: no event (censored), 6,423 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 950 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6392-01A-11D-1704-01): tumor purity 0.83, ploidy 2.07, whole-genome doublings 0.
